CCDI case PBBUPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/4eaad9d8-88a9-490a-9392-32e9b8dcf22b

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Myxoid liposarcoma: ICD-O-3 morphology code: 8852/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 16.5 years (6,033 days).

Biospecimens (2 samples)
- Sample 0DI1L4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI3JY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
